Surgical pathology report (de-identified scan), TCGA case TCGA-R6-A6L6, project TCGA-ESCA (Esophageal Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R6-A6L6-01B (Primary Tumor).

ICD-O-3
Adenocarcinoma NOS 8140/3
Site ^{66CF} Distal third esophagus
path Esophagus NOS C15.9
Jw 6/25/13

Specimen Date/Time:

DIAGNOSIS

(A) ESOPHAGUS, TUMOR, BIOPSY:

ULCERATED, INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA FOCALLY UNDERLYING SQUAMOUS EPITHELIUM. (SEE COMMENT)

Overlying and separate fragments of squamous mucosa with reactive epithelial changes.

(B) ESOPHAGUS, 29 CM, BIOPSY:

SMALL FOCUS OF INVASIVE ADENOCARCINOMA (LESS THAN 1 MM) INVOLVING ONE OF MULTIPLE TISSUE FRAGMENTS.

TUMOR INVADES AT LEAST INTO LAMINA PROPRIA.

Adjoining and separate fragments of distinctive-type Barrett mucosa with low-grade dysplasia and active chronic inflammation.

Squamous mucosa with reactive epithelial changes.

COMMENT

The tumor focally infiltrates desmoplastic stroma, which suggests submucosal invasion. Clinical correlation is recommended.

GROSS DESCRIPTION

(A) TUMOR – Multiple tan soft tissue fragments aggregating 1.0 x 0.6 x 0.2 cm submitted in toto A1.

(B) ESOPHAGUS AT 29, RULE OUT BARRETT'S – Three tan soft tissue fragments aggregating 0.5 x 0.4 x 0.2 cm. Submitted in toto B1.

CLINICAL HISTORY

Esophageal cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

These tests have not been

-----END OF REPORT-----

II/PAI Discrepancy		

Source: NCI Genomic Data Commons file 1fa97d73-e119-46b4-866b-2942665cb975 (TCGA-R6-A6L6.E644D486-D66D-46E8-9F05-4F9FBD66E9BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).